Somatic mutation profile of tumor specimen MP2PRT-PASPJJ-TMP1-A (aliquot MP2PRT-PASPJJ-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASPJJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,221 days).
Specimen MP2PRT-PASPJJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2d67148-5e22-42f2-8cc6-de2d600473b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASPJJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASPJJ-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36c0da6e-cda7-4557-b4cd-e5d5ddc78ffd

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK2 | c.5759C>T p.T1920M | Missense Mutation (SNP) | VAF 153/545 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs372914995; called by muse, mutect2, varscan2
- ARHGAP22 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 46/655 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs369200749, COSV50932711; called by muse, mutect2
- ARHGEF11 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347868807, COSV63810156; called by muse, varscan2
- CEP126 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 37/113 reads (33%) | catalogued as rs374091656; called by muse, mutect2, varscan2
- FGF21 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 73/408 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs139679302; called by muse, mutect2, varscan2
- KIAA1210 | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 188/436 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs769417029; called by muse, mutect2, varscan2
- P3H3 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs1555121483, COSV51834417; called by muse, mutect2, varscan2
- BPI | c.925A>T p.M309L (on ENST00000262865; = p.M305L on NM_001725.3) | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, varscan2
- COL4A5 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 69/549 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DNAH5 | c.5051C>T p.T1684I | Missense Mutation (SNP) | VAF 154/360 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.208); called by muse, varscan2
- IGKJ4 | c.1_2insCTGAGCGC p.L1Pfs*? | Frame Shift Ins (INS) | VAF 94/304 reads (31%) | called by pindel, varscan2
- IGKV1D-16 | chr2:90100737 CTCCCACAGTGTT>GG | Missense Mutation (DEL) | VAF 38/73 reads (52%) | called by mutect2*, pindel
- MUC16 | c.13883G>T p.G4628V | Missense Mutation (SNP) | VAF 221/458 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- AP1S3 | c.135G>A p.R45= | Silent (SNP) | VAF 159/351 reads (45%) | called by muse, mutect2, varscan2
- PRDM16 | c.708C>T p.D236= | Silent (SNP) | VAF 151/342 reads (44%) | catalogued as rs1270070289; called by muse, mutect2, varscan2
